Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFA, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAFA-01A (Primary Tumor).

Department of Pathology

IAD 0-3
Seminoma NOS 9061/3
Site @ Testis NOS 062.9
QW 8/3/14

Direct dial

Mobile

Internal postal address

E-mai

Date

Concerning

Summary pathology report

Left orchidectomy; seminoma; diameter 4.5 cm; tumor confined to testis in available slides; no angio-invasion; no invasion in rete testis.

Date of procurement (= date of orchidectomy)

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 0c425969-3a34-4891-b7b6-eb935d93f3c7 (TCGA-2G-AAFA-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).